Somatic mutation profile of tumor specimen MMRF_1285_1_BM_CD138pos (aliquot MMRF_1285_1_BM_CD138pos_T2_KHS5U_L15099) from MMRF case MMRF_1285, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.3 years (27,512 days).
Specimen MMRF_1285_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8cb30d1-ea19-4b6c-9ff3-c483c153e925.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1285_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1285_1_PB_Whole_C1_KHS5U_L15100; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dd23e22-7523-4523-b718-be8aea136348

The open-access MAF lists 184 somatic variants for this specimen: 68 protein-altering or splice-affecting, 25 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 50, Silent 25, Intron 24, 5'UTR 7, 3'Flank 6, Nonsense Mutation 4, 5'Flank 3, Frame Shift Del 3, Splice Site 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNNM1 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs761658293, COSV63202446; called by muse, mutect2, varscan2
- CYP2B6 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1209959748; called by muse, mutect2
- DCAF12L1 | c.879C>A p.S293R | Missense Mutation (SNP) | VAF 75/84 reads (89%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.594); catalogued as COSV64421863, COSV64422822; called by muse, mutect2, varscan2
- FMN2 | c.4330A>T p.I1444F | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60425059; called by muse, mutect2, varscan2
- GPATCH2L | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as rs781733578; called by muse, mutect2, varscan2
- GPR179 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as rs201405656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR4 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1469399830, COSV59916303, COSV59916377; called by muse, mutect2, varscan2
- GZF1 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as COSV100582676; called by muse, mutect2, varscan2
- LAMB3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs762942741, COSV61920286; called by muse, mutect2, varscan2
- LKAAEAR1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 66/87 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1319141240; called by muse, mutect2, varscan2
- LRP1B | c.6007G>C p.V2003L | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV67274279; called by muse, mutect2, varscan2
- MYO7A | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.181); catalogued as COSV101289129; called by muse, mutect2, varscan2
- PLCH2 | c.4175A>C p.D1392A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs1169642720; called by muse, mutect2, varscan2
- PLCZ1 | c.972_973del p.V326Kfs*25 | Frame Shift Del (DEL) | VAF 63/184 reads (34%) | catalogued as rs777169092; called by mutect2, pindel, varscan2
- PLEKHM1 | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166779321; called by muse, mutect2, varscan2
- RBSN | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1452059614; called by muse, mutect2, varscan2
- RFX2 | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV57945944; called by muse, mutect2, varscan2
- SDF4 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV99767293; called by muse, mutect2
- SLC25A5 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58625899; called by muse, mutect2, varscan2
- SMIM7 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs779327008, COSV62417775; called by muse, mutect2, varscan2
- SOX4 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1179311144, COSV55193493; called by muse, mutect2
- SOX4 | c.1193A>C p.D398A | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1239245615, COSV55193503, COSV55193724; called by muse, mutect2
- USH2A | c.4627+2T>C p.X1543_splice (on ENST00000307340 / NM_206933.4; = p.G1543= on NM_007123.6) | Splice Site (SNP) | VAF 74/139 reads (53%) | catalogued as CS136560; called by muse, mutect2, varscan2
- ZNF292 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60546480; called by muse, mutect2, varscan2
- ZNF57 | c.516A>T p.E172D | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs776397346; called by muse, mutect2, varscan2
- ADCY5 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 111/215 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASPSCR1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ASTN2 | c.3521C>T p.T1174I (on ENST00000313400 / NM_001365069.1; = p.T1123I on NM_014010.5) | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ATP2B2 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C1GALT1 | c.875A>C p.Y292S | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- C3orf56 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCNE2 | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 124/240 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ELN | c.1607C>A p.A536D | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESX1 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 61/64 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM135B | c.2036C>G p.S679C | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM214A | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- FAT3 | c.5353A>T p.N1785Y | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMN2 | c.4331T>A p.I1444N | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT18 | c.1421A>G p.Q474R | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLP2R | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2
- GTF2IRD2B | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 39/269 reads (14%) | called by muse, mutect2, varscan2
- HEG1 | c.2599G>C p.V867L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLA-DQB1 | c.661+5G>A | Splice Region (SNP) | VAF 87/250 reads (35%) | called by muse, mutect2, varscan2
- IRF4 | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMCD1 | c.339T>G p.F113L | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- LRCH4 | c.949-4del | Splice Region (DEL) | VAF 64/226 reads (28%) | called by mutect2, pindel*, varscan2
- MAFA | c.676C>G p.R226G | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.367); called by muse, varscan2
- MECOM | c.955C>A p.P319T (on ENST00000468789 / NM_001105078.4; = p.P507T on NM_004991.4) | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MOCOS | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PCDHGB4 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- POTEA | c.311A>C p.H104P | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PPFIBP1 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- RAB11FIP5 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIN2 | c.1252G>C p.E418Q (on ENST00000255006 / NM_001242581.1; = p.E369Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEMA4A | c.1541G>T p.C514F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SVIL | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TAP1 | c.778+1G>C p.X260_splice | Splice Site (SNP) | VAF 55/97 reads (57%) | called by muse, mutect2, varscan2
- TRAF3 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- TRAF3 | c.1502del p.Q501Rfs*28 | Frame Shift Del (DEL) | VAF 9/108 reads (8%) | called by mutect2, pindel
- TRIM9 | c.1714A>C p.T572P | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TRIOBP | c.3052A>T p.I1018F | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TSPAN33 | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ZFP30 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, varscan2
- ZFPM2 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 74/161 reads (46%) | called by muse, mutect2, varscan2
- ZNF443 | c.925del p.Y309Ifs*48 | Frame Shift Del (DEL) | VAF 124/527 reads (24%) | called by mutect2, pindel, varscan2
- ZNF470 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 103/164 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF568 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF883 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ADCY8 | c.762C>A p.T254= | Silent (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- ALOX12B | c.981G>A p.V327= | Silent (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- ANKRD24 | c.2889G>A p.A963= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as rs781160528; called by muse, mutect2, varscan2
- C12orf40 | c.894T>C p.S298= | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- CDS1 | c.448C>T p.L150= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV55687037; called by muse, mutect2, varscan2
- DLG2 | c.384T>C p.F128= | Silent (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- FAP | c.1125A>G p.K375= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs1363568858; called by muse, mutect2, varscan2
- FCER2 | c.531C>T p.F177= | Silent (SNP) | VAF 80/283 reads (28%) | catalogued as rs536515427, COSV60915956, COSV60916707; called by muse, mutect2, varscan2
- GRID2IP | c.186C>T p.R62= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs1200862109; called by muse, mutect2, varscan2
- HEATR1 | c.750G>A p.L250= | Silent (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- INPP5D | c.2058G>A p.V686= (on ENST00000445964 / NM_001017915.3; = p.V685= on NM_005541.5) | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as rs1266688100, COSV100856614; called by muse, mutect2, varscan2
- JPT1 | c.243A>C p.G81= | Silent (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- KRT24 | c.591A>C p.S197= | Silent (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- KRT73 | c.1086G>A p.S362= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs759355959, COSV59840034; called by muse, mutect2, varscan2
- LRP1B | c.6378T>A p.L2126= | Silent (SNP) | VAF 62/252 reads (25%) | called by muse, mutect2, varscan2
- MAPKAP1 | c.468T>G p.P156= | Silent (SNP) | VAF 51/408 reads (13%) | called by muse, mutect2, varscan2
- MROH9 | c.1851A>G p.K617= | Silent (SNP) | VAF 34/326 reads (10%) | called by muse, mutect2
- OR2J3 | c.204C>T p.N68= | Silent (SNP) | VAF 133/445 reads (30%) | catalogued as rs201161327, COSV101013642; called by muse, mutect2, varscan2
- OSCAR | c.477G>A p.R159= | Silent (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2
- PDZD3 | c.169C>T p.L57= | Silent (SNP) | VAF 201/340 reads (59%) | catalogued as rs748694859; called by muse, mutect2, varscan2
- PTPRD | c.174C>T p.N58= | Silent (SNP) | VAF 63/245 reads (26%) | called by muse, mutect2, varscan2
- STKLD1 | c.232C>T p.L78= | Silent (SNP) | VAF 100/354 reads (28%) | called by muse, mutect2, varscan2
- ZBTB40 | c.2802T>C p.N934= | Silent (SNP) | VAF 87/193 reads (45%) | catalogued as rs1461864693; called by muse, mutect2, varscan2
- ZNF169 | c.1314T>C p.G438= | Silent (SNP) | VAF 96/291 reads (33%) | catalogued as rs1176664150; called by muse, mutect2, varscan2
- ZNF608 | c.2850T>C p.G950= | Silent (SNP) | VAF 14/414 reads (3%) | called by muse, mutect2
- ABRAXAS1 | c.87+33G>C | Intron (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.*246T>C | 3'UTR (SNP) | VAF 63/190 reads (33%) | called by muse, mutect2, varscan2
- ALPL | c.*37A>G | 3'UTR (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- AP1S1 | c.*608C>G | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- C1QL2 | c.-228G>A | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- C1QTNF3 | c.482-78G>A | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2
- C1orf109 | c.456-18T>C | Intron (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81947026 A>G | 3'Flank (SNP) | VAF 94/141 reads (67%) | called by muse, mutect2, varscan2
- CALHM5 | c.*4032C>A | 3'UTR (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- CAMSAP1 | c.*2565C>T | 3'UTR (SNP) | VAF 68/219 reads (31%) | called by muse, mutect2, varscan2
- CASC3 | c.*881A>C | 3'UTR (SNP) | VAF 79/157 reads (50%) | called by muse, mutect2, varscan2
- CCDC77 | c.*265T>G | 3'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- CCL14 | c.*49G>C | 3'UTR (SNP) | VAF 69/126 reads (55%) | called by muse, mutect2, varscan2
- CCNY | c.*1448G>T | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- CDH8 | c.*1379C>T | 3'UTR (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- CFAP43 | c.1442+521C>A | Intron (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- CKMT2 | c.*78C>T | 3'UTR (SNP) | VAF 56/212 reads (26%) | called by muse, mutect2, varscan2
- CLK3 | c.-28T>G | 5'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, varscan2
- COL5A1 | c.*228C>T | 3'UTR (SNP) | VAF 50/211 reads (24%) | called by muse, mutect2, varscan2
- COPB1 | c.1737+102A>T | Intron (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- CPNE8 | c.1144-10del | Intron (DEL) | VAF 47/128 reads (37%) | called by mutect2, pindel, varscan2
- CUX1 | c.*1411C>A | 3'UTR (SNP) | VAF 88/308 reads (29%) | called by muse, mutect2, varscan2
- DAAM2 | c.258+97A>G | Intron (SNP) | VAF 8/149 reads (5%) | catalogued as rs1216452142; called by muse, mutect2
- DIAPH1 | c.*1244C>A | 3'UTR (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- DIO2 | c.*1149C>T | 3'UTR (SNP) | VAF 31/39 reads (79%) | called by muse, mutect2, varscan2
- DISC1 | c.1117+20800G>T | Intron (SNP) | VAF 39/136 reads (29%) | catalogued as rs996160294; called by muse, mutect2, varscan2
- DNAJC24 | c.*2011T>G | 3'UTR (SNP) | VAF 49/54 reads (91%) | called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.*1206C>A | 3'UTR (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- EFNA5 | c.*3022G>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*678G>T | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2
- EMP2 | c.*360C>T | 3'UTR (SNP) | VAF 88/195 reads (45%) | called by muse, mutect2, varscan2
- FMN1 | c.*4926T>C | 3'UTR (SNP) | VAF 46/75 reads (61%) | called by muse, mutect2, varscan2
- GABRA4 | c.*7834T>A | 3'UTR (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- GADL1 | c.-66G>C | 5'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- GADL1 | c.-67G>C | 5'UTR (SNP) | VAF 36/109 reads (33%) | catalogued as rs769120355; called by muse, mutect2, varscan2
- GOT2 | c.*229del | 3'UTR (DEL) | VAF 109/354 reads (31%) | catalogued as rs1247302278; called by mutect2, pindel, varscan2
- GRIK4 | c.2266+29G>T | Intron (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- GRM7 | c.519+94662A>T | Intron (SNP) | VAF 107/205 reads (52%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+236C>T | Intron (SNP) | VAF 75/256 reads (29%) | called by muse, mutect2, varscan2
- KIAA2012 | c.1908+58T>C | Intron (SNP) | VAF 73/174 reads (42%) | called by muse, mutect2, varscan2
- L1TD1 | c.-24T>G | 5'UTR (SNP) | VAF 101/250 reads (40%) | called by muse, mutect2, varscan2
- L1TD1 | c.-23C>A | 5'UTR (SNP) | VAF 101/248 reads (41%) | called by muse, mutect2, varscan2
- LRRC10 | c.*76G>T | 3'UTR (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- MAEL | c.225+105del | Intron (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- MAFK | c.*1803C>T | 3'UTR (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- MIEF1 | c.*2383A>G | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- MTARC2 | c.*335A>C | 3'UTR (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- MYEF2 | c.*2021C>T | 3'UTR (SNP) | VAF 33/111 reads (30%) | catalogued as rs912397620; called by muse, mutect2, varscan2
- MYF5 | c.*237G>A | 3'UTR (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- MYO5C | c.*263G>C | 3'UTR (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- NAB1 | c.*1475A>C | 3'UTR (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- NAP1L4 | c.607-52C>T | Intron (SNP) | VAF 22/34 reads (65%) | called by muse, mutect2, varscan2
- NHLH2 | chr1:115841196 G>C | 5'Flank (SNP) | VAF 34/77 reads (44%) | catalogued as COSV57201698; called by muse, mutect2, varscan2
- NTRK3 | chr15:87871797 A>G | 3'Flank (SNP) | VAF 57/119 reads (48%) | catalogued as rs990860431; called by muse, mutect2, varscan2
- NYAP2 | c.*1606C>A | 3'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- OR2A12 | chr7:144096177 T>A | 3'Flank (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2
- PARVA | c.*2469_*2471del | 3'UTR (DEL) | VAF 11/60 reads (18%) | called by pindel, varscan2
- PGAP1 | c.1952+156G>C | Intron (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.*499G>A | 3'UTR (SNP) | VAF 95/231 reads (41%) | called by muse, mutect2, varscan2
- PKIA | chr8:78603869 T>A | 3'Flank (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2
- PKIA | chr8:78603871 T>G | 3'Flank (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2
- PLOD3 | c.680-32G>T | Intron (SNP) | VAF 52/188 reads (28%) | called by muse, mutect2, varscan2
- PLOD3 | c.680-33G>C | Intron (SNP) | VAF 53/189 reads (28%) | called by muse, mutect2, varscan2
- POLR3E | c.1944+164A>T | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- PPARGC1A | c.234+299A>C | Intron (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82978507 del G | 3'Flank (DEL) | VAF 6/42 reads (14%) | catalogued as rs1416417208; called by pindel, varscan2
- RALGPS1 | c.*936C>T | 3'UTR (SNP) | VAF 122/390 reads (31%) | called by muse, mutect2, varscan2
- RAX2 | c.*162G>C | 3'UTR (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- RBL1 | c.*1657G>A | 3'UTR (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- RIF1 | c.*1998A>C | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- RIPK3 | chr14:24339999 C>T | 5'Flank (SNP) | VAF 11/282 reads (4%) | called by muse, mutect2
- RNF169 | c.*641G>T | 3'UTR (SNP) | VAF 96/101 reads (95%) | called by muse, mutect2, varscan2
- ROCK2 | c.*79A>G | 3'UTR (SNP) | VAF 133/302 reads (44%) | called by muse, mutect2, varscan2
- SCD | c.*3066T>G | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- SLC27A3 | c.2030+9C>T | Intron (SNP) | VAF 7/102 reads (7%) | catalogued as rs761040962; called by muse, mutect2
- SNX17 | c.*304C>T | 3'UTR (SNP) | VAF 89/180 reads (49%) | catalogued as rs1558309169; called by muse, mutect2, varscan2
- SPG21 | c.*129A>T | 3'UTR (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- STK32A | c.435-101T>A | Intron (SNP) | VAF 42/116 reads (36%) | catalogued as rs1023286004; called by muse, mutect2, varscan2
- STRIP2 | c.1476+45T>A | Intron (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- TBRG4 | chr7:45111719 T>C | 5'Flank (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- TBXAS1 | c.333+2258A>T | Intron (SNP) | VAF 47/150 reads (31%) | called by muse, mutect2, varscan2
- TEAD1 | c.*5494A>G | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- TMEM250 | c.*67G>A | 3'UTR (SNP) | VAF 49/143 reads (34%) | catalogued as rs1243601904; called by muse, mutect2, varscan2
- TMEM41A | c.*533_*534insC | 3'UTR (INS) | VAF 14/33 reads (42%) | called by mutect2, varscan2
- TRAK2 | c.-64G>A | 5'UTR (SNP) | VAF 12/187 reads (6%) | catalogued as COSV100217147; called by muse, mutect2
- TTLL3 | c.*298C>T | 3'UTR (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- TTN | c.10360+4337A>C | Intron (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- UGGT1 | c.*1361C>T | 3'UTR (SNP) | VAF 57/123 reads (46%) | called by muse, mutect2, varscan2
- VWC2L | c.*1097G>A | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.*2042G>C | 3'UTR (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- ZNF725P | n.1106A>C | RNA (SNP) | VAF 80/206 reads (39%) | called by muse, mutect2, varscan2
